Gene-level copy-number profile of tumor specimen ALCH-B1LJ-TTP1-A from ALCHEMIST case ALCH-B1LJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.0 years (26,282 days).
Specimen ALCH-B1LJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d586e019-30ad-47a7-8e4e-d6503dc8f5da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1LJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/673907e9-085a-4862-8008-fd757cb9d674

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 11; copy number 2: 2,412; copy number 3: 1,041; copy number 4: 34,228; copy number 5: 484; copy number 6: 18,168; copy number 7: 73; copy number 8: 2,285; copy number 9: 45; copy number 11: 2; copy number 12: 9; copy number 14: 101; copy number 15: 1; copy number 18: 26.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,398,614–22,128,103, 28 genes: IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 184 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,568,527, 2 genes, copy number 11 (within-gene range 6–11): UGT2B29P, UGT2B17.
- chr14:34,541,044–35,809,304, 40 genes, copy number 9 (within-gene range 8–9): AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1.
- chr16:84,053,761–84,116,942, 2 genes, copy number 9: MBTPS1, AC040169.3.
- chr17:18,411,159–18,425,097, 3 genes, copy number 9 (within-gene range 7–9): LINC02076, KRT17P5, YWHAEP2.
- chr17:18,476,737–18,551,705, 5 genes, copy number 12 (within-gene range 4–12): LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr22:36,510,855–39,155,945, 127 genes, copy number 12–18 (broad region; genes not listed).
- chr22:40,857,077–40,932,815, 1 gene, copy number 14 (within-gene range 8–14): XPNPEP3.
- chr22:40,917,111–41,045,591, 4 genes, copy number 14–15: Metazoa_SRP, RNU6-379P, RBX1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
